Surgical pathology report (de-identified scan), TCGA case TCGA-55-6980, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6980-01A (Primary Tumor).

[page 1 of 3]
SEE REPORT

SURGICAL PATHOLOGY REPORT

PROCEDURE DATE:

==== SPECIMEN DESCRIPTION: =====

- A. INFERIOR PULMONARY LIGAMENT LYMPH NODE
- B. RIGHT LOWER LOBE OF LUNG,
- C. TRACHEAL LYMPH NODE N2
- D. SUBCARINAL LYMPH NODE

==== PRE-OPERATIVE DIAGNOSIS: =====

Right lower lobe lung nodule

==== POST-OPERATIVE DIAGNOSIS: =====

Same, pending pathology

==== CLINICAL INFORMATION: =====

Right lower lobe nodule

==== INTRAOPERATIVE CONSULTATION: =====

BPC DIAGNOSIS: "Non-small cell carcinoma; lesion inked black" by

==== GROSS DESCRIPTION: =====

- A. Received is a brown-black encapsulated lymph node, measuring 1.0 x 0.8 x 0.3 cm. Sectioning reveals a hyperpigmented cut surface. The specimen is entirely submitted in one cassette.
- B. Received in formalin is a previously sectioned lobe of lung, weighing 144 grams and measuring 20.2 x 19.2 x 4.8 cm. The pleura is tan-pink with a minimal amount of scattered anthracotic pigmentation. There is a staple line, measuring 7.7 cm, present along the medial aspect of the lobe. The staple line is located adjacent to the bronchial margin. The bronchial margin is unremarkable. The bronchi are dissected. There is a minimal amount of mucus located within the lumen. The hilar vessels are patent with a minimal amount of fatty streaks. There is a previously sectioned indurated nodule, measuring 1.5 x 1.5 x 0.8 cm, located 2.6 cm from the hilar margin. The outer surface is inked black. Sectioning through the lesion reveals an ill-defined yellow-white cut surface. The lesion does not disrupt the overlying pleura. The surrounding pulmonary parenchyma is pink-red and fleshy. No other lesions are identified. Three gray-black hyperpigmented lymph nodes are found surrounding the hilum, measuring up to 0.4 cm in greatest dimension. Representative sections are submitted in seven cassettes as follows: cassette 1 - bronchial and vascular margins; cassette 2 - staple line margin; cassettes 3 and 4 - entire lesion; cassette 5 - three intact possible lymph nodes; cassettes 6 and 7 - random lung parenchyma.

[page 2 of 3]
[REDACTED]

Patient

MRN

DOB

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name

Status

Requester [REDACTED]

Surgical Report

DXSTIC

BPC. Received is a tan-pink to white fleshy portion of soft tissue, measuring 1.2 x 0.9 x 0.3 cm. The specimen is entirely submitted in one cassette.

C. Received in formalin is a portion of tan-yellow fibrofatty tissue, measuring 3.8 x 2.2 x 0.3 cm. Sectioning reveals an indurated hyperpigmented nodule resembling a lymph node, measuring 0.9 cm in greatest dimension. The specimen is entirely submitted in two cassettes as follows: cassette 1 - bisected lymph node; cassette 2 - remaining soft tissue.

D. Received is a portion of tan-yellow fibrofatty tissue, measuring 2.3 x 2.0 x 0.6 cm. Sectioning reveals a hyperpigmented nodule resembling a lymph node, measuring 0.8 cm in greatest dimension. The specimen is entirely submitted in two cassettes as follows: cassette 1 - bisected lymph node; cassette 2 - remaining soft tissue.

==== MICROSCOPIC DESCRIPTION: =====

A. One slide is examined. Sections of the lymph node show sinus histiocytosis with anthracosis. No metastatic tumor is present.

B. Sections on slides B3 and B4 show a subcapsular tumor with the morphology of well differentiated invasive adenocarcinoma of bronchoalveolar pattern. The tumor occurs in linear arrays of tumor lining the alveolar spaces. There is a small central scar. No vascular invasion is present. There is no penetration of the visceral pleura. The rest of the lung shows changes of mild chronic obstructive pulmonary disease. The bronchial resection margin is free of tumor. Sections of intrapulmonary lymph nodes on slide B6 show sinus histiocytosis with anthracosis. No metastatic tumor is present.

BPC. One slide is examined. Sections show similar tumor as described above.

C. Two slides are examined. Sections of the lymph node show sinus histiocytosis with anthracosis. No metastatic tumor is present.

D. Two slides are examined. Sections of the lymph nodes show sinus histiocytosis with anthracosis. No metastatic tumor is present.

==== FINAL DIAGNOSIS: =====

A. LYMPH NODE, INFERIOR PULMONARY LIGAMENT:

1. NO METASTATIC TUMOR

2. SINUS HISTIOCYTOSIS WITH FOCAL ANTHRACOSIS

RIGHT LUNG, LOWER LOBE, RESECTION:

1. HISTOLOGIC TYPE: ADENOCARCINOMA, BRONCHOALVEOLAR TYPE

2. HISTOLOGIC GRADE: WELL DIFFERENTIATED

3. EXTENT OF INVASION: pT1 (MAXIMAL DIAMETER OF TUMOR IS 1.5 CM)

4. MARGINS: NOT INVOLVED

5. BLOOD/LYMPHATIC VESSEL INVASION: ABSENT

6. REGIONAL LYMPH NODES: NOT INVOLVED (SEE A, C, AND D)

[page 3 of 3]
[REDACTED]

Patient

MRN

DOB

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name

Status

Requester [REDACTED]

Surgical Report

DXSTIC

7. DISTANT METASTASIS: NOT KNOWN

C. LYMPH NODE, TRACHEAL, N2:

1. NO METASTATIC TUMOR IN ONE LYMPH NODE

2. SINUS HISTIOCYTOSIS WITH ANTHRACOSIS

D. LYMPH NODE, SUBCARINAL, EXCISION:

1. NO METASTATIC TUMOR IN ONE LYMPH NODE

2. SINUS HISTIOCYTOSIS WITH ANTHRACOSIS

A-MALIGNANT

[REDACTED]

Source: NCI Genomic Data Commons file ff2fc6d4-4060-4096-8310-208dc502c163 (TCGA-55-6980.E73AAD2D-83D3-46B2-B2E9-CC93C5FBD670.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).